Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A7R8, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A7R8-01A (Primary Tumor).

ICD-O-3
Astrocytoma, grade III 9401/3
Site ~~Cerebrum~~ Brain, supratentorial NOS 71.0
~~Pituitary~~ Brain NOS 71.9
9/09/27/13

Diagnosis
Anaplastic astrocytoma WHO grade III

untranslating original report
is housed at the BCR.

Source: NCI Genomic Data Commons file 5214c348-98e9-440b-91eb-91809af81a35 (TCGA-S9-A7R8.7287E887-2783-4416-8C61-718C6247C982.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).